Somatic mutation profile of tumor specimen TCGA-ZB-A96O-01A (aliquot TCGA-ZB-A96O-01A-11D-A428-09) from TCGA case TCGA-ZB-A96O, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type B1, malignant; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 54.2 years (19,782 days).
Specimen TCGA-ZB-A96O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e810b40-9d0d-4747-9a78-827fb1515d03.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZB-A96O-10A (Blood Derived Normal), aliquot TCGA-ZB-A96O-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2afa81e-ab57-4b81-b922-4cdfd8837733

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPRS | c.1336C>A p.Q446K | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.588); called by muse, mutect2
